Somatic mutation profile of tumor specimen TCGA-EE-A29P-06A (aliquot TCGA-EE-A29P-06A-11D-A197-08) from TCGA case TCGA-EE-A29P, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 77.3 years (28,249 days).
Specimen TCGA-EE-A29P-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cbc9071-bba7-424a-803a-1247ad9b108b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A29P-10A (Blood Derived Normal), aliquot TCGA-EE-A29P-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52e01d88-a0cd-4300-aed8-fca675b21c9c

The open-access MAF lists 369 somatic variants for this specimen: 235 protein-altering or splice-affecting, 126 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 210, Silent 126, Nonsense Mutation 12, RNA 6, Splice Region 5, Frame Shift Del 3, Splice Site 3, 3'UTR 1, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CNOT9 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs267599211, COSV55298957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRXCR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 48/137 reads (35%) | catalogued as rs761349153, CM153971, COSV67670021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- RYR1 | c.7522C>T p.R2508C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs118192178, CM061936, CM061937, COSV62088665; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCB5 | c.3053G>A p.R1018Q (on ENST00000404938 / NM_001163941.2; = p.R573Q on NM_178559.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.178); catalogued as rs781568123, COSV99328926; called by mutect2, varscan2
- AC097636.1 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV71309405; called by muse, mutect2, varscan2
- ACSM1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54632909, COSV99533646; called by muse, mutect2, varscan2
- ADAMTS6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as COSV66856688; called by muse, mutect2, varscan2
- ADGRB3 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV65382332, COSV65390606; called by muse, mutect2, varscan2
- ADGRL2 | c.1037C>T p.T346I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54651868; called by muse, mutect2, varscan2
- AGTPBP1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV61268486; called by muse, mutect2, varscan2
- AHNAK2 | c.3250G>A p.V1084M | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100318233; called by muse, mutect2, varscan2
- AL662899.2 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV65507668; called by muse, mutect2, varscan2
- ALPK2 | c.5173G>A p.E1725K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV64490239; called by muse, mutect2, varscan2
- AMBRA1 | c.3611C>T p.S1204F (on ENST00000458649 / NM_001367468.1; = p.S1114F on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.044); catalogued as COSV54048403; called by muse, mutect2, varscan2
- ANKRD30A | c.1078G>A p.E360K (on ENST00000611781; = p.E304K on NM_052997.2) | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77379875; called by mutect2, varscan2
- ASH1L | c.296C>T p.P99L | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64205369; called by muse, mutect2, varscan2
- ATF7IP2 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.188); catalogued as COSV61092178; called by muse, varscan2
- ATP1A2 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63402242; called by muse, mutect2, varscan2
- AZIN2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs750759779, COSV99613556; called by muse, varscan2
- BOD1L1 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV50006492; called by muse, mutect2, varscan2
- BPIFB4 | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs764105327, COSV64950644; called by muse, mutect2, varscan2
- BVES | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58946553; called by muse, mutect2, varscan2
- C2CD6 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV53790647, COSV53791117; called by muse, mutect2, varscan2
- C5AR2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs267605553, COSV57255439; called by muse, mutect2, varscan2
- CACNA1A | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); catalogued as COSV64189509; called by muse, mutect2, varscan2
- CADM4 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV55928114; called by muse, mutect2, varscan2
- CATSPER4 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100128454; called by mutect2, varscan2
- CCDC97 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752926768, COSV54189434; called by muse, mutect2
- CCNA1 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55219835; called by muse, mutect2, varscan2
- CCR7 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV55850831; called by muse, mutect2
- CD4 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV50589060; called by muse, mutect2, varscan2
- CD5L | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs900252489, COSV63821064, COSV63821551; called by muse, mutect2, varscan2
- CD69 | c.293T>C p.F98S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV57302225; called by muse, mutect2, varscan2
- CD93 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55663849; called by muse, mutect2, varscan2
- CDH13 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV51790005; called by mutect2, varscan2
- CECR2 | c.2789C>T p.P930L (on ENST00000342247 / NM_001290047.2; = p.P747L on NM_001290046.1) | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as COSV52835981; called by muse, mutect2, varscan2
- CFAP221 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs866442055, COSV54653915; called by muse, mutect2, varscan2
- CHRNA2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); catalogued as rs1299700179, COSV53556352, COSV53556461; called by muse, mutect2, varscan2
- CLCA1 | c.1990A>G p.T664A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52324981; called by muse, mutect2, varscan2
- CNST | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.853); catalogued as COSV63621453; called by muse, mutect2, varscan2
- CNTNAP2 | c.1384C>T p.R462C | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs769071764, COSV62144657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.127); catalogued as COSV65421248; called by muse, mutect2, varscan2
- COL4A1 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV65421253; called by muse, mutect2, varscan2
- COL4A6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs765808425, COSV57859125; called by muse, mutect2, varscan2
- COL8A1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV99658609; called by muse, mutect2
- CPED1 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV59997018, COSV60010339; called by muse, mutect2, varscan2
- CSMD1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs770518582, COSV68166947; called by muse, mutect2, varscan2
- CYP2A6 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.019); catalogued as COSV56533670; called by muse, mutect2, varscan2
- DAZL | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV51711856, COSV51714569; called by muse, mutect2, varscan2
- DCC | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV59083747; called by muse, mutect2, varscan2
- DGKG | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs567513651, COSV53961477; called by muse, mutect2, varscan2
- DGKK | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); catalogued as COSV65706341; called by muse, mutect2, varscan2
- DGKQ | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as rs1363697855, COSV56615951; called by muse, mutect2, varscan2
- DLG2 | c.310-1G>A p.X104_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | catalogued as COSV54621035, COSV99719590; called by muse, mutect2, varscan2
- DMBT1 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV57534148; called by muse, mutect2, varscan2
- DNAH10 | c.10697G>A p.G3566E (on ENST00000409039; = p.G3505E on NM_207437.3) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1484842273, COSV68987759; called by muse, mutect2, varscan2
- DNAH3 | c.7510G>A p.D2504N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54502939; called by muse, mutect2, varscan2
- DNAH5 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1388732051, COSV54203252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSG2 | c.429A>C p.L143F | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55196628; called by muse, mutect2
- EHHADH | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.15); catalogued as COSV51627662; called by muse, mutect2, varscan2
- EIF4G1 | c.1993G>A p.D665N (on ENST00000346169 / NM_198241.3; = p.D469N on NM_004953.5) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59989000, COSV59992638; called by muse, mutect2, varscan2
- EPHA2 | c.2657A>G p.D886G | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.601); catalogued as rs1444591722, COSV64452065; called by muse, mutect2, varscan2
- ERBB4 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53501228; called by muse, mutect2, varscan2
- ERICH3 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV58598926; called by muse, mutect2, varscan2
- ERICH3 | c.3368G>A p.G1123E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58598935; called by muse, varscan2
- FAM149A | c.1062C>G p.C354W (on ENST00000356371 / NM_001367768.2; = p.C63W on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV57025654, COSV57027054; called by muse, mutect2, varscan2
- FAM170A | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as rs761614536, COSV58923871; called by muse, mutect2
- FAM47C | c.1417C>T p.H473Y | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.958); catalogued as COSV100792932, COSV63723569; called by muse, mutect2, varscan2
- FAT4 | c.7535C>T p.S2512F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58671324; called by muse, mutect2, varscan2
- FAT4 | c.14401C>T p.R4801C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199895179, COSV58671338; called by muse, mutect2, varscan2
- FMO3 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV63006440; called by muse, mutect2, varscan2
- FRAS1 | c.8011G>A p.E2671K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760160124, COSV53588710; called by mutect2, varscan2
- FYB2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58582850; called by muse, mutect2, varscan2
- G6PD | c.1310A>T p.Y437F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63702270; called by muse, mutect2, varscan2
- GH2 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 16/228 reads (7%) | catalogued as rs1288013640, COSV60426246; called by muse, mutect2
- GJA8 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99569547; called by muse, mutect2, varscan2
- GLYR1 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58925519; called by muse, mutect2, varscan2
- GNL3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV66920811; called by muse, mutect2, varscan2
- GPR63 | c.1045T>A p.F349I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57739515, COSV57741933; called by muse, mutect2, varscan2
- HECTD4 | c.10316C>T p.T3439I | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV66386606; called by muse, mutect2, varscan2
- HELLS | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV53294375; called by muse, mutect2, varscan2
- IGSF1 | c.1194G>A p.W398* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV63836039; called by muse, mutect2, varscan2
- IGSF9B | c.2225C>T p.T742I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.189); catalogued as COSV100318024; called by muse, mutect2, varscan2
- IL36G | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV52077742; called by muse, mutect2, varscan2
- IL36RN | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61010283; called by muse, mutect2, varscan2
- IPO11 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57571863; called by muse, mutect2, varscan2
- ITGA4 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.831); catalogued as COSV67896210; called by muse, mutect2, varscan2
- KANSL1L | c.2665C>T p.L889F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55989425; called by muse, mutect2, varscan2
- KCNK13 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV56410532, COSV56416312; called by muse, mutect2, varscan2
- KCNMB2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV64200392; called by muse, mutect2, varscan2
- KCNQ5 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.3); catalogued as COSV59654856; called by muse, mutect2, varscan2
- KIAA0232 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.26); catalogued as rs1210399666, COSV56923255; called by muse, mutect2, varscan2
- KIZ | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754527224, COSV55683534; called by muse, mutect2, varscan2
- KPTN | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV54548591; called by muse, mutect2, varscan2
- LRAT | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.413); catalogued as COSV60476428; called by muse, mutect2, varscan2
- LRRC43 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV60287958; called by muse, mutect2, varscan2
- LRRC8E | c.698C>A p.A233D | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60716914; called by muse, mutect2, varscan2
- LY6H | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV61370284; called by muse, mutect2, varscan2
- MARCHF10 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs921322735, COSV60885155; called by muse, mutect2, varscan2
- MARF1 | c.3617+1G>C p.X1206_splice | Splice Site (SNP) | VAF 3/43 reads (7%) | catalogued as COSV60028819; called by muse, mutect2
- MECOM | c.1567C>T p.P523S (on ENST00000468789 / NM_001105078.4; = p.P711S on NM_004991.4) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV52959454; called by muse, mutect2, varscan2
- MGAM | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV101527441, COSV72073576; called by muse, mutect2
- MIB2 | c.1065C>T p.L355= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as rs374674829; called by mutect2, varscan2
- MIXL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs769845658, COSV64729003; called by mutect2, varscan2
- MMP25 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60678581; called by muse, mutect2, varscan2
- MMUT | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs573727541, COSV51272292; called by muse, mutect2
- MPPED2 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764358251, COSV63896032, COSV63899134, COSV63899956; called by muse, mutect2, varscan2
- MUC16 | c.40550C>T p.P13517L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as rs367916400; called by muse, mutect2, varscan2
- MUC16 | c.32776G>C p.V10926L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as COSV67444134; called by muse, mutect2, varscan2
- MUC16 | c.26555C>T p.P8852L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV67444147; called by muse, mutect2, varscan2
- MUC16 | c.20224C>T p.P6742S | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV67444155; called by muse, mutect2, varscan2
- MUC16 | c.6281C>T p.S2094L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as rs1455279926, COSV67444162; called by muse, mutect2, varscan2
- MYBPHL | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764945362, COSV64062137; called by muse, mutect2, varscan2
- MYH11 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.099); catalogued as COSV55542727; called by muse, mutect2, varscan2
- MYO16 | c.4987C>T p.P1663S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as rs867955877, COSV100696154, COSV62745178; called by muse, mutect2, varscan2
- NDST1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as rs150060318; called by mutect2, varscan2
- NEK5 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs1206308830, COSV62878809; called by muse, mutect2, varscan2
- NID2 | c.3124C>T p.Q1042* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99356884; called by muse, mutect2, varscan2
- NLGN4X | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV52004189, COSV99320988; called by muse, mutect2, varscan2
- NLRP8 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.574); catalogued as COSV52583255; called by muse, mutect2, varscan2
- NPY5R | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV100642737, COSV58450937; called by muse, mutect2, varscan2
- NXPE4 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV64943379; called by muse, mutect2, varscan2
- OCEL1 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV52242757; called by muse, mutect2, varscan2
- OR4C13 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV73648619; called by muse, mutect2, varscan2
- OR4D10 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456707940, COSV73259965; called by muse, mutect2, varscan2
- OR9A4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71884957; called by muse, mutect2, varscan2
- OTOGL | c.7024C>T p.L2342F (on ENST00000547103; = p.L2333F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV54012946; called by muse, mutect2, varscan2
- PAPLN | c.2809C>T p.P937S (on ENST00000554301; = p.P910S on NM_173462.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as COSV53712928, COSV53720159; called by muse, mutect2, varscan2
- PAPPA2 | c.1258C>A p.R420S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62772065, COSV62772735; called by muse, mutect2, varscan2
- PARM1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV56649941; called by muse, mutect2, varscan2
- PAX8 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs775083174, CM076375, COSV54506393; called by mutect2, varscan2
- PCDH15 | c.5024C>T p.P1675L (on ENST00000644397 / NM_001354429.2; = p.P1617L on NM_001142771.2) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.4); catalogued as COSV100905056; called by muse, mutect2, varscan2
- PCDH15 | c.5023C>T p.P1675S (on ENST00000644397 / NM_001354429.2; = p.P1617S on NM_001142771.2) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.011); catalogued as rs1371823914, COSV100905057; called by muse, mutect2, varscan2
- PCDHB5 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1307227233, COSV50647275; called by mutect2, varscan2
- PCSK6 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.443); catalogued as COSV59338168; called by muse, mutect2, varscan2
- PDE4D | c.653G>A p.G218E (on ENST00000340635 / NM_001104631.2; = p.G82E on NM_006203.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58939352; called by muse, mutect2, varscan2
- PID1 | c.641C>T p.A214V (on ENST00000354069 / NM_001330156.1; = p.A212V on NM_017933.5) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); catalogued as COSV62472451; called by muse, mutect2, varscan2
- PKD1L1 | c.6607C>T p.H2203Y | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.266); catalogued as COSV56957799; called by muse, mutect2, varscan2
- PLXNA4 | c.1721A>T p.N574I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as COSV58104419; called by muse, varscan2
- PLXNA4 | c.1649G>A p.R550K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV58104437; called by muse, varscan2
- PPP1R16B | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as rs780281154, COSV55374084; called by muse, varscan2
- PRB4 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV54395134; called by muse, mutect2, varscan2
- PREX2 | c.4115G>A p.G1372E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55750307; called by muse, mutect2, varscan2
- PTH2R | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55913709; called by muse, mutect2, varscan2
- PTPRT | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776642212, COSV61959822; called by muse, mutect2, varscan2
- PTPRT | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV61959832; called by muse, mutect2, varscan2
- PWWP3B | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs768908416, COSV61798262; called by muse, mutect2, varscan2
- RALGAPA1 | c.5267A>C p.Q1756P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.222); catalogued as COSV51876371; called by muse, mutect2, varscan2
- RBM25 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.641); catalogued as COSV56198488; called by muse, mutect2, varscan2
- RIMS2 | c.1692G>A p.L564= (on ENST00000666250 / NM_001348490.2; = p.L372= on NM_014677.5 and 7 other RefSeq transcripts) | Splice Region (SNP) | VAF 24/85 reads (28%) | catalogued as COSV51652740; called by muse, mutect2, varscan2
- RIT1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as COSV100851198; called by muse, mutect2, varscan2
- RIT1 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV100851199; called by muse, mutect2, varscan2
- RLF | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs142953276; called by muse, mutect2, varscan2
- RP1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55109883; called by muse, mutect2, varscan2
- RP1 | c.2737C>T p.Q913* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV55109896, COSV55122131; called by muse, mutect2, varscan2
- RYR2 | c.6145G>C p.E2049Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV63661105; called by muse, mutect2, varscan2
- SAMD9 | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV66072957, COSV66076701; called by muse, mutect2, varscan2
- SELL | c.958G>A p.G320R (on ENST00000650983; = p.G307R on NM_000655.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV52549924; called by mutect2, varscan2
- SERINC3 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.493); catalogued as rs11559232, COSV99667879; called by muse, mutect2, varscan2
- SETBP1 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV56312772; called by muse, mutect2, varscan2
- SH3RF1 | c.2315C>T p.S772F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV52918170, COSV52919354; called by mutect2, varscan2
- SHROOM4 | c.3101C>T p.S1034L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56784077; called by muse, mutect2, varscan2
- SIRPB1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54374122; called by muse, mutect2, varscan2
- SLC17A8 | c.1561G>A p.G521R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV60121813; called by muse, mutect2, varscan2
- SLC2A10 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100826386; called by muse, mutect2, varscan2
- SLC30A10 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV63070405, COSV63074070; called by muse, mutect2, varscan2
- SLC36A2 | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV58861978; called by muse, mutect2, varscan2
- SLC39A1 | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57841007; called by muse, mutect2, varscan2
- SLCO3A1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV59224809; called by muse, mutect2, varscan2
- SNAP91 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.949); catalogued as COSV52115002; called by muse, mutect2, varscan2
- SPANXN3 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.919); catalogued as rs782300196, COSV65139954; called by muse, mutect2, varscan2
- SPATA16 | c.1538T>G p.L513R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651387; called by muse, mutect2, varscan2
- SPOCK1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs148446530; called by muse, mutect2, varscan2
- SPTA1 | c.7188G>A p.M2396I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs376052117, COSV63523813; called by muse, mutect2, varscan2
- SQOR | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52940652; called by muse, varscan2
- ST18 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52484096; called by muse, mutect2, varscan2
- STAB2 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66334015; called by muse, mutect2, varscan2
- SULT1A1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59086605; called by muse, mutect2, varscan2
- SUN1 | c.490G>A p.A164T (on ENST00000405266 / NM_001367651.1; = p.A114T on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as COSV61777382; called by muse, mutect2, varscan2
- SV2C | c.1211G>A p.R404K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV59213831; called by muse, mutect2, varscan2
- TAS1R2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV64743548; called by muse, mutect2, varscan2
- TBATA | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as rs1345208711, COSV100165281, COSV54717228; called by muse, mutect2, varscan2
- TCHH | c.4129C>T p.L1377F | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.137); catalogued as COSV64272724; called by muse, mutect2, varscan2
- TCN1 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV57252052; called by muse, mutect2, varscan2
- TENM1 | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.109); catalogued as rs774847643, COSV64424941; called by muse, mutect2, varscan2
- TFCP2L1 | c.912C>T p.H304= | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as rs777622009, COSV99748451; called by muse, mutect2, varscan2
- TMC7 | c.1664G>A p.W555* | Nonsense Mutation (SNP) | VAF 84/298 reads (28%) | catalogued as COSV58581478; called by muse, mutect2, varscan2
- TNK2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57365675; called by muse, mutect2, varscan2
- TNXB | c.6142G>A p.G2048S (on ENST00000647633; = p.G1801S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1413064915, COSV64473169; called by muse, mutect2, varscan2
- TRANK1 | c.2408C>T p.S803F | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV57140268; called by muse, mutect2, varscan2
- TRMT11 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200225212, COSV57672023; called by muse, mutect2, varscan2
- TRPC6 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV60250821; called by muse, mutect2, varscan2
- TSBP1 | c.1342G>A p.G448R (on ENST00000617061; = p.G453R on NM_006781.5) | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV66657517; called by muse, mutect2, varscan2
- TSPOAP1 | c.5372C>T p.P1791L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99271768; called by muse, varscan2
- TSPOAP1 | c.5371C>T p.P1791S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.21); PolyPhen probably damaging (1); catalogued as COSV99271771; called by muse, varscan2
- TTN | c.26474C>T p.S8825L (on ENST00000591111; = p.S7898L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | PolyPhen benign (0.003); catalogued as rs781609380, COSV59883482; ClinVar: uncertain significance; called by mutect2, varscan2
- TTN | c.4570G>A p.D1524N (on ENST00000591111; = p.D1478N on NM_003319.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | PolyPhen probably damaging (0.998); catalogued as COSV100634311, COSV59883530; called by muse, mutect2, varscan2
- UBE2NL | c.106C>T p.H36Y | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs267606376; called by muse, mutect2, varscan2
- UBR4 | c.11890C>T p.L3964= | Splice Region (SNP) | VAF 15/100 reads (15%) | catalogued as COSV64382741; called by muse, mutect2, varscan2
- UGP2 | c.1422A>G p.G474= | Splice Region (SNP) | VAF 8/39 reads (21%) | catalogued as COSV55437524; called by muse, mutect2, varscan2
- UGT2A2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.231); catalogued as COSV54138004; called by muse, mutect2, varscan2
- ULBP3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV66253959; called by muse, mutect2, varscan2
- ULK3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV71348042; called by muse, mutect2, varscan2
- UNC45B | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs34242925; called by mutect2, varscan2
- UNC79 | c.2746C>T p.P916S (on ENST00000393151 / NM_001346218.2; = p.P739S on NM_020818.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV56373475; called by muse, mutect2
- UPF2 | c.1580T>G p.I527S | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.84); catalogued as COSV62658198; called by muse, mutect2, varscan2
- USH2A | c.9934G>A p.G3312R | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV56326806; called by muse, mutect2, varscan2
- USP26 | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.59); catalogued as COSV63708012; called by muse, mutect2, varscan2
- USP35 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.084); catalogued as COSV71572596; called by muse, mutect2, varscan2
- UTP14C | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV73000849; called by muse, mutect2, varscan2
- UTP6 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55571444; called by muse, mutect2, varscan2
- VSTM1 | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 26/104 reads (25%) | catalogued as COSV58073826; called by muse, mutect2, varscan2
- WDR88 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs1267965453, COSV50111154; called by muse, mutect2, varscan2
- WFDC8 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.039); catalogued as rs373025670, COSV51488520; called by muse, mutect2, varscan2
- WFIKKN1 | c.1550G>A p.G517D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770349267, COSV50192831; called by mutect2, varscan2
- XIRP2 | c.3214C>T p.P1072S (on ENST00000628543; = p.P1247S on NM_152381.6) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.752); catalogued as COSV54682227; called by muse, mutect2, varscan2
- ZBED9 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV71729157; called by muse, mutect2, varscan2
- ZBTB17 | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100998987, COSV100999040; called by muse, mutect2, varscan2
- ZBTB17 | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as rs773987964, COSV100998953, COSV100999041; called by muse, mutect2, varscan2
- ZNF136 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.61); catalogued as rs867955627, COSV59709985; called by muse, mutect2, varscan2
- ZNF160 | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61998912; called by muse, mutect2, varscan2
- ZNF185 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100248528; called by mutect2, varscan2
- ZNF560 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV56865264; called by muse, mutect2, varscan2
- ZNF98 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.19); catalogued as COSV63334337; called by muse, mutect2, varscan2
- AHNAK | c.8684_8695del p.P2895_M2899delinsL | In Frame Del (DEL) | VAF 27/183 reads (15%) | called by mutect2, pindel, varscan2
- FBXO45 | c.743_776del p.E248Gfs*17 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | called by mutect2, pindel
- MRC1 | c.2015C>T p.T672M | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTTP | c.894del p.C298* | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- PTEN | c.867dup p.V290Sfs*8 | Frame Shift Ins (INS) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- SIGLEC6 | c.534del p.I179Sfs*39 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- TPTE | c.1112A>G p.E371G (on ENST00000618007 / NM_199261.4; = p.E353G on NM_199259.4) | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); called by muse, mutect2
- USP6NL | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.212); called by muse, mutect2
- ADGRV1 | c.7770C>T p.S2590= | Silent (SNP) | VAF 17/206 reads (8%) | catalogued as rs201767905, CD122146, COSV67978296; called by muse, mutect2
- AHNAK2 | c.3249G>A p.K1083= | Silent (SNP) | VAF 51/187 reads (27%) | catalogued as rs999077696, COSV100318234; called by muse, mutect2, varscan2
- ALB | c.417G>A p.L139= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- ALPK2 | c.4341C>T p.I1447= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV64490244; called by muse, mutect2, varscan2
- ANGEL1 | c.1983C>T p.A661= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV51871823; called by muse, mutect2, varscan2
- AQP1 | c.318C>T p.I106= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs375712827; called by muse, mutect2, varscan2
- ASIC2 | c.1128G>A p.V376= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV56755484; called by muse, mutect2, varscan2
- ATG7 | c.1134C>T p.G378= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs572456428, COSV61611014; called by muse, mutect2, varscan2
- AUTS2 | c.933G>A p.T311= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1464933744, COSV61382880; called by muse, mutect2, varscan2
- AZIN2 | c.1233C>T p.S411= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99613553; called by muse, varscan2
- C19orf18 | c.190T>C p.L64= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV58705081; called by muse, mutect2, varscan2
- CACNA1B | c.519C>T p.V173= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs201010988, COSV53113418; called by muse, mutect2, varscan2
- CACNA1C | c.3792G>A p.V1264= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV59696408; called by muse, mutect2
- CCDC102B | c.1458C>T p.I486= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV60134316; called by muse, mutect2, varscan2
- CCR7 | c.117G>A p.V39= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99878750; called by mutect2, varscan2
- CD1E | c.45G>A p.G15= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs994306541, COSV63769919; called by muse, mutect2, varscan2
- CD93 | c.1473G>A p.G491= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99849364; called by muse, mutect2, varscan2
- CDCA2 | c.1059T>C p.D353= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100399025, COSV57944268; called by muse, mutect2, varscan2
- CIR1 | c.33G>A p.K11= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as rs770545829, COSV55807090, COSV55808655; called by muse, mutect2, varscan2
- CLEC14A | c.693C>T p.I231= | Silent (SNP) | VAF 23/135 reads (17%) | catalogued as COSV60561668; called by muse, mutect2, varscan2
- CLRN1 | c.639C>T p.F213= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV55804612; called by muse, mutect2, varscan2
- CSNK1A1L | c.195G>A p.T65= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV65789341; called by muse, mutect2, varscan2
- CYP2J2 | c.1242G>A p.E414= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV64605429; called by muse, mutect2, varscan2
- CYP4F2 | c.1428G>A p.A476= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV55616254; called by muse, varscan2
- DNAH3 | c.7710G>A p.G2570= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs1422901510, COSV54502923; called by muse, mutect2, varscan2
- DNAI4 | c.1227G>A p.R409= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV64021461; called by muse, mutect2, varscan2
- DSCAM | c.1881G>A p.T627= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs765038367, COSV68020688, COSV68029560; called by mutect2, varscan2
- EIF2AK1 | c.1146C>T p.I382= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV52236001; called by muse, mutect2, varscan2
- FCRL5 | c.2067C>T p.I689= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs1252182690, COSV62511369; called by muse, mutect2, varscan2
- FCRL6 | c.702C>T p.S234= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV58939909; called by muse, mutect2, varscan2
- FGB | c.417G>A p.Q139= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV57417466; called by muse, mutect2, varscan2
- FILIP1L | c.564G>A p.K188= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV58764806; called by muse, mutect2
- FMN2 | c.2211G>A p.R737= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1249783646, COSV60416668; called by muse, mutect2
- FSTL5 | c.1005C>T p.F335= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV60181051; called by muse, mutect2, varscan2
- GALNT3 | c.903C>T p.V301= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs767806161, COSV67061365; called by muse, mutect2, varscan2
- GDF5 | c.1101G>A p.K367= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as COSV100976844, COSV65499254, COSV65501420; called by muse, mutect2, varscan2
- GIGYF1 | c.1863C>T p.P621= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1408617537, COSV51939234; called by muse, mutect2, varscan2
- GJA8 | c.108C>T p.I36= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as rs781829394, COSV53788493, COSV53788636; called by muse, mutect2, varscan2
- GP5 | c.597T>C p.L199= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV55461427; called by muse, mutect2, varscan2
- GUCY1A1 | c.1275G>A p.L425= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs577597869, COSV56649056; called by muse, mutect2, varscan2
- HCAR1 | c.252G>A p.G84= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV63671096; called by muse, mutect2
- HEATR1 | c.1908A>G p.L636= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV63979779; called by muse, mutect2, varscan2
- HECTD1 | c.2559T>A p.R853= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV65991119; called by mutect2, varscan2
- HERC5 | c.705C>T p.S235= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs1350525482, COSV52037220; called by muse, mutect2, varscan2
- HHIPL2 | c.1974G>A p.Q658= | Silent (SNP) | VAF 130/352 reads (37%) | catalogued as COSV58563156; called by muse, mutect2, varscan2
- HLTF | c.327C>T p.G109= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV59498751; called by muse, mutect2, varscan2
- IFNA16 | c.183C>T p.F61= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs1412574268, COSV66509759; called by muse, mutect2, varscan2
- IFNW1 | c.462G>A p.L154= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV66521772, COSV66522499; called by muse, mutect2, varscan2
- IGSF10 | c.3042G>A p.R1014= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs766931700, COSV56781415; called by muse, mutect2, varscan2
- IL7 | c.55C>T p.L19= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV55672638; called by muse, mutect2, varscan2
- INPP5B | c.1449C>T p.A483= (on ENST00000373023; = p.A403= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV65959369; called by muse, mutect2, varscan2
- KCNAB2 | c.738G>A p.L246= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV51235631; called by muse, varscan2
- KCNH5 | c.984C>T p.L328= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV59751986; called by muse, mutect2, varscan2
- KCNQ5 | c.2472G>A p.K824= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100572468; called by muse, mutect2, varscan2
- KCTD16 | c.1206C>T p.F402= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV72576646; called by muse, mutect2, varscan2
- LARP1 | c.1017C>T p.G339= (on ENST00000518297 / NM_033551.3; = p.G262= on NM_015315.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs780690848, COSV60424570; called by muse, mutect2, varscan2
- MAGEA10 | c.921G>A p.R307= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV54882812, COSV99726816; called by muse, mutect2, varscan2
- MAP2K3 | c.876C>T p.D292= (on ENST00000342679 / NM_145109.3; = p.D263= on NM_002756.4) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100384182; called by muse, mutect2, varscan2
- MCTP1 | c.1140C>T p.I380= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as COSV56503847; called by muse, mutect2, varscan2
- MMP16 | c.954G>A p.R318= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV54150810; called by muse, mutect2, varscan2
- MUC16 | c.30591G>A p.Q10197= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV67444141, COSV67475474; called by muse, mutect2, varscan2
- MYH4 | c.3450C>T p.I1150= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as COSV55112060; called by muse, mutect2, varscan2
- MYH8 | c.1746G>A p.L582= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV67959638, COSV67972128; called by muse, mutect2, varscan2
- MYLK2 | c.186G>A p.G62= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- MYOZ2 | c.312C>T p.A104= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV61084030, COSV61086016; called by muse, mutect2, varscan2
- NAE1 | c.1488C>T p.F496= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV51974938; called by muse, mutect2, varscan2
- NEB | c.12216C>T p.S4072= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99425341; called by muse, mutect2, varscan2
- NEUROD1 | c.597G>A p.Q199= | Silent (SNP) | VAF 46/241 reads (19%) | catalogued as COSV54548123; called by muse, mutect2, varscan2
- NFIX | c.795C>T p.S265= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV62175547; called by muse, mutect2, varscan2
- NFKBID | c.453C>T p.F151= (on ENST00000396901; = p.F303= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs774855934, COSV61727724; called by muse, mutect2, varscan2
- NXN | c.1230G>A p.V410= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs570513548, COSV61093867; called by muse, mutect2, varscan2
- OR10Z1 | c.186C>T p.F62= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as COSV63523809; called by muse, mutect2, varscan2
- OR13G1 | c.177C>T p.F59= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62943353, COSV62943685; called by muse, mutect2
- OR2M2 | c.450C>T p.I150= | Silent (SNP) | VAF 95/176 reads (54%) | catalogued as COSV62897765; called by muse, mutect2, varscan2
- OR4A5 | c.333C>T p.F111= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1156629694, COSV60521461, COSV60522988; called by muse, mutect2, varscan2
- OR4M1 | c.660C>T p.F220= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs1179453313, COSV60059367; called by muse, mutect2, varscan2
- OR5P3 | c.255C>T p.F85= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as rs1259963415, COSV60428882; called by muse, mutect2, varscan2
- PCDHA3 | c.1854G>A p.A618= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1554122551, COSV63538759; called by mutect2, varscan2
- PCDHB10 | c.978C>T p.G326= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV53375274; called by muse, mutect2, varscan2
- PCDHGB3 | c.1545C>T p.F515= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1561553418, COSV53897476; called by muse, mutect2, varscan2
- PCDHGB7 | c.1914C>T p.V638= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV53897733; called by muse, mutect2, varscan2
- PCLO | c.11130C>T p.T3710= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV61615585; called by muse, mutect2, varscan2
- PLCH1 | c.3798C>T p.T1266= (on ENST00000340059 / NM_001130960.2; = p.T1258= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV58186214; called by muse, mutect2, varscan2
- PLEKHG4B | c.1401C>T p.L467= (on ENST00000283426; = p.L823= on NM_052909.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52043346; called by muse, mutect2, varscan2
- PSG7 | c.33G>A p.Q11= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV68444240; called by muse, mutect2, varscan2
- PTPN9 | c.750C>T p.F250= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60722401; called by muse, mutect2, varscan2
- PZP | c.2361T>C p.S787= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs1307051090, COSV54354284; called by muse, mutect2, varscan2
- RAB27B | c.321C>T p.F107= | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV50494271; called by muse, mutect2, varscan2
- RASAL3 | c.2325C>T p.L775= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1444323854, COSV54604599; called by muse, mutect2
- RAVER1 | c.1201C>T p.L401= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV53343651; called by muse, mutect2, varscan2
- RETREG2 | c.1395C>T p.S465= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV56086903; called by muse, mutect2, varscan2
- RHOU | c.771C>T p.F257= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs761227727, COSV64208259; called by muse, mutect2, varscan2
- RPS6KA6 | c.438G>A p.G146= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1229039437, COSV53115568; called by muse, mutect2, varscan2
- SCN11A | c.2352A>C p.S784= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56565557; called by muse, mutect2, varscan2
- SEMA3A | c.537C>T p.S179= | Silent (SNP) | VAF 66/171 reads (39%) | catalogued as COSV54861552; called by muse, mutect2, varscan2
- SERINC3 | c.420C>T p.A140= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV99667882; called by muse, mutect2, varscan2
- SETDB2 | c.1074C>T p.N358= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV51643203; called by muse, mutect2, varscan2
- SLC26A6 | c.780C>T p.P260= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs766126229, COSV50839838; called by muse, mutect2, varscan2
- SLC34A2 | c.1113C>T p.L371= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as COSV65940598; called by muse, mutect2, varscan2
- SLC44A3 | c.948C>T p.F316= (on ENST00000271227 / NM_001114106.3; = p.F268= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV54727660; called by muse, mutect2, varscan2
- SLC45A1 | c.783C>T p.A261= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV57092848; called by muse, mutect2, varscan2
- SLC6A20 | c.1425G>A p.V475= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV62070087; called by muse, mutect2, varscan2
- SLC7A14 | c.402C>T p.F134= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs772249542, COSV51577748, COSV99200942; called by muse, mutect2, varscan2
- STXBP5L | c.1146G>A p.L382= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56499787, COSV99875552; called by muse, mutect2, varscan2
- TAS2R41 | c.720C>T p.L240= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs207468692, COSV68764914; called by muse, mutect2, varscan2
- TBC1D1 | c.2013C>T p.T671= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV54714003; called by muse, mutect2, varscan2
- TECPR2 | c.3480C>T p.P1160= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV63968957; called by muse, mutect2, varscan2
- TENM2 | c.3609C>T p.F1203= (on ENST00000518659 / NM_001122679.2; = p.F971= on NM_001080428.3) | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1317667169, COSV69122526; called by muse, mutect2, varscan2
- TFCP2L1 | c.913C>T p.L305= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV55294005, COSV99748447; called by muse, mutect2, varscan2
- TMEM119 | c.510G>A p.R170= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV101219512; called by muse, mutect2, varscan2
- TMEM132B | c.459G>A p.T153= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs757343384, COSV54744468, COSV54771471; called by muse, mutect2, varscan2
- TMEM168 | c.285C>T p.S95= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV57179215; called by muse, mutect2, varscan2
- TRBC2 | c.444C>T p.L148= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1182684311; called by muse, mutect2, varscan2
- TRIM36 | c.2145A>G p.E715= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV56688071; called by muse, mutect2, varscan2
- TTN | c.33132G>A p.E11044= (on ENST00000591111; = p.E10117= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV59883475; called by muse, mutect2, varscan2
- UBE4A | c.264C>T p.I88= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV52802656; called by muse, mutect2, varscan2
- UCP1 | c.117C>T p.V39= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99530360; called by muse, mutect2, varscan2
- UTP14C | c.1473C>T p.A491= | Silent (SNP) | VAF 31/148 reads (21%) | catalogued as COSV101584359; called by muse, mutect2, varscan2
- VWA5A | c.774A>G p.G258= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV63707153; called by muse, mutect2, varscan2
- WDR49 | c.210C>T p.F70= (on ENST00000308378 / NM_001366158.1; = p.F411= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV57702022; called by muse, mutect2, varscan2
- ZBED2 | c.552G>A p.V184= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1314375338, COSV51912581; called by muse, mutect2, varscan2
- ZNF185 | c.963C>T p.L321= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1437988239, COSV100248526; called by muse, mutect2, varscan2
- ZNF274 | c.429C>T p.P143= (on ENST00000610905; = p.P38= on NM_016324.3) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV58762899; called by muse, mutect2, varscan2
- ZNF366 | c.1086G>A p.G362= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV59213747; called by muse, mutect2, varscan2
- ZNF385B | c.348C>A p.T116= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as rs764932543, COSV61174998; called by muse, mutect2, varscan2
- ZNF562 | c.528C>T p.S176= (on ENST00000453372 / NM_001130032.2; = p.S104= on NM_017656.4) | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV53332606; called by muse, mutect2
- FOLH1B | n.1832C>T | RNA (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2
- KCTD7 | c.*22C>T | 3'UTR (SNP) | VAF 13/57 reads (23%) | catalogued as COSV51876081; called by muse, mutect2, varscan2
- MAGEA5 | n.103G>A | RNA (SNP) | VAF 18/43 reads (42%) | catalogued as rs868418825; called by muse, mutect2, varscan2
- MIR520F | n.86G>A | RNA (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- PKD1L2 | n.210G>A | RNA (SNP) | VAF 9/27 reads (33%) | catalogued as rs1399444779; called by muse, mutect2, varscan2
- RPL23AP42 | n.144G>A | RNA (SNP) | VAF 15/47 reads (32%) | catalogued as rs370269714; called by muse, mutect2, varscan2
- USP32 | c.1239+4598C>T | Intron (SNP) | VAF 29/66 reads (44%) | catalogued as COSV100342394; called by muse, mutect2, varscan2
- VN1R10P | n.417A>T | RNA (SNP) | VAF 89/211 reads (42%) | catalogued as rs1561793875; called by muse, mutect2, varscan2
